Somatic mutation profile of tumor specimen bd266bdd-12e4-42cb-9c49-911bfc (aliquot bd266bdd-12e4-42cb-9c49-911bfc_D6) from CPTAC case 04OV063, project CPTAC-2 (Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IV.
Specimen bd266bdd-12e4-42cb-9c49-911bfc: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a5297df-5764-4f0d-be8b-279e50231d89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1c7e6865-4a6b-41ee-8e3b-456330 (Blood Derived Normal), aliquot 1c7e6865-4a6b-41ee-8e3b-456330_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96e7ffec-58bd-4637-a709-0aa0a04bfd2a

The open-access MAF lists 100 somatic variants for this specimen: 64 protein-altering or splice-affecting, 24 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 24, 5'UTR 3, Frame Shift Del 3, RNA 3, Splice Site 2, Intron 2, 3'UTR 2, Splice Region 2, Frame Shift Ins 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CADPS2 | c.710A>G p.E237G | Missense Mutation (SNP) | VAF 60/302 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763466758; called by muse, mutect2, varscan2
- CEP290 | c.6566G>T p.S2189I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100468172; called by muse, mutect2
- CROCC | c.3224C>T p.S1075L | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV65014236; called by muse, mutect2, varscan2
- EEF2KMT | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 107/403 reads (27%) | catalogued as COSV52159666; called by mutect2, varscan2
- FGF6 | c.415G>A p.V139I | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs759669908, COSV57403617; called by mutect2, varscan2
- IQGAP2 | c.3640G>C p.E1214Q | Missense Mutation (SNP) | VAF 45/64 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57171911; called by muse, mutect2, varscan2
- PEG3 | c.4120G>T p.V1374F | Missense Mutation (SNP) | VAF 128/365 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as rs558829653, COSV55626181; called by muse, mutect2, varscan2
- PKD1 | c.1361G>A p.R454H | Missense Mutation (SNP) | VAF 126/224 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1244006755; called by muse, mutect2, varscan2
- SESTD1 | c.2072T>C p.M691T | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as rs1191141076; called by muse, mutect2, varscan2
- TCEA2 | c.891+5G>A | Splice Region (SNP) | VAF 72/199 reads (36%) | catalogued as rs1393294795; called by muse, mutect2, varscan2
- TP53 | c.250del p.A84Pfs*39 | Frame Shift Del (DEL) | VAF 75/158 reads (47%) | catalogued as COSV53077353; called by mutect2, pindel, varscan2
- TTN | c.27188G>T p.G9063V (on ENST00000591111; = p.G8136V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | PolyPhen probably damaging (1); catalogued as rs397517528, COSV100629388; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UGGT1 | c.1349C>A p.A450D | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV52141379; called by muse, mutect2
- ACIN1 | c.1862C>G p.A621G | Missense Mutation (SNP) | VAF 85/220 reads (39%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ACOT11 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACOT9 | c.1151A>C p.Q384P | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- AGTR1 | c.538T>A p.C180S | Missense Mutation (SNP) | VAF 157/329 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARSG | c.347T>A p.L116H | Missense Mutation (SNP) | VAF 129/194 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BTN3A3 | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 101/264 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- C1GALT1 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 56/258 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CAPRIN2 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CFAP57 | c.3361A>C p.K1121Q (on ENST00000372492 / NM_001378189.1; = p.K1154Q on NM_001195831.3) | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DNAAF5 | c.1241C>A p.A414E | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.001); called by muse, mutect2
- FAM71E2 | c.2551A>C p.K851Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FSCN2 | c.1076G>T p.G359V | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUT10 | c.1309A>G p.S437G | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GCDH | c.957G>A p.R319= | Splice Region (SNP) | VAF 46/424 reads (11%) | called by muse, mutect2, varscan2
- GCDH | c.958A>T p.M320L | Missense Mutation (SNP) | VAF 46/424 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDF2 | c.611C>G p.T204S | Missense Mutation (SNP) | VAF 142/377 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GPR179 | c.6299G>T p.G2100V (on ENST00000621958; = p.G2099V on NM_001004334.4) | Missense Mutation (SNP) | VAF 91/176 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GPR37 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 72/157 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC9 | c.904C>A p.Q302K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- HPS4 | c.734T>C p.I245T | Missense Mutation (SNP) | VAF 173/329 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- HTRA4 | c.772-2A>T p.X258_splice | Splice Site (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2
- JRK | c.1314_1317dup p.W440Qfs*34 | Frame Shift Ins (INS) | VAF 300/799 reads (38%) | called by mutect2, pindel, varscan2
- KCNH5 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 123/351 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LOXHD1 | c.4369C>G p.L1457V | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP1A | c.3857G>A p.R1286K | Missense Mutation (SNP) | VAF 89/169 reads (53%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MAP7D3 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MROH2A | c.1804C>A p.L602I | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEIL3 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- OR13F1 | c.871A>T p.S291C | Missense Mutation (SNP) | VAF 92/170 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDCL2 | c.29G>T p.W10L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PLEKHF2 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 148/567 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PNPLA5 | c.110G>T p.R37L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.436); called by muse, mutect2
- PPIL6 | c.636A>G p.I212M | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- RABGEF1 | c.1014G>C p.K338N (on ENST00000439720 / NM_001287061.2; = p.K325N on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RNASEH1 | c.564+1G>T p.X188_splice | Splice Site (SNP) | VAF 47/114 reads (41%) | called by muse, mutect2, varscan2
- RP1L1 | c.5306C>G p.A1769G | Missense Mutation (SNP) | VAF 198/545 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SALL3 | c.1745A>C p.E582A | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SCN3A | c.5905T>C p.S1969P | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- SSH3 | c.1199_1208+1del | Frame Shift Del (DEL) | VAF 27/143 reads (19%) | called by mutect2, pindel, varscan2
- TAT | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 155/415 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- TECTA | c.743A>C p.K248T | Missense Mutation (SNP) | VAF 156/273 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- TMEM248 | c.481A>C p.T161P | Missense Mutation (SNP) | VAF 87/213 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TMEM82 | c.509T>A p.L170H | Missense Mutation (SNP) | VAF 188/275 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- TNKS | c.3355C>G p.Q1119E | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- UNC13B | c.1280T>G p.L427R | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- VIM | c.1215del p.G406Afs*16 | Frame Shift Del (DEL) | VAF 133/450 reads (30%) | called by mutect2, pindel, varscan2
- WARS2 | c.626C>A p.S209Y | Missense Mutation (SNP) | VAF 62/105 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- YEATS2 | c.2969C>G p.S990C | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFR | c.803A>G p.Y268C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF443 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 115/465 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF674 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACOT9 | c.687C>A p.L229= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- APOB | c.2313G>A p.P771= | Silent (SNP) | VAF 89/310 reads (29%) | catalogued as rs552986140; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARRDC2 | c.1032G>A p.E344= | Silent (SNP) | VAF 54/173 reads (31%) | called by muse, mutect2, varscan2
- CCDC180 | c.1473G>A p.E491= | Silent (SNP) | VAF 46/91 reads (51%) | catalogued as rs1460350007, COSV63832634; called by muse, mutect2, varscan2
- DPYS | c.1203T>A p.A401= | Silent (SNP) | VAF 127/364 reads (35%) | called by muse, mutect2, varscan2
- EXOSC1 | c.249C>A p.A83= | Silent (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- FAT4 | c.8178A>G p.E2726= | Silent (SNP) | VAF 107/287 reads (37%) | called by muse, mutect2, varscan2
- GPR179 | c.6300C>T p.G2100= (on ENST00000621958; = p.G2099= on NM_001004334.4) | Silent (SNP) | VAF 91/176 reads (52%) | catalogued as rs1158201197; called by muse, mutect2, varscan2
- HELZ2 | c.2556C>T p.G852= (on ENST00000467148 / NM_001037335.2; = p.G283= on NM_033405.3) | Silent (SNP) | VAF 41/304 reads (13%) | called by muse, mutect2, varscan2
- HOOK3 | c.1665G>A p.L555= | Silent (SNP) | VAF 11/63 reads (17%) | called by muse, varscan2
- ITGA10 | c.2475G>C p.L825= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- KRTAP27-1 | c.393C>T p.C131= | Silent (SNP) | VAF 197/329 reads (60%) | catalogued as rs773301245; called by muse, mutect2, varscan2
- MTCL1 | c.2241C>T p.A747= (on ENST00000306329 / NM_001378206.1; = p.A387= on NM_015210.4) | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as rs575618091; called by muse, mutect2, varscan2
- NIPSNAP3A | c.546A>T p.G182= | Silent (SNP) | VAF 69/129 reads (53%) | called by muse, mutect2, varscan2
- POTEH | c.1032T>A p.T344= | Silent (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- PRDM10 | c.2616G>T p.T872= | Silent (SNP) | VAF 120/200 reads (60%) | called by muse, mutect2, varscan2
- RPGRIP1 | c.2922C>T p.P974= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- RSAD2 | c.651T>G p.A217= | Silent (SNP) | VAF 34/250 reads (14%) | catalogued as COSV65908143; called by muse, mutect2, varscan2
- SLC35G3 | c.735G>A p.V245= | Silent (SNP) | VAF 187/366 reads (51%) | called by muse, mutect2, varscan2
- SPNS2 | c.693G>T p.L231= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV100223761; called by muse, mutect2, varscan2
- UTP3 | c.561G>A p.E187= | Silent (SNP) | VAF 71/203 reads (35%) | called by muse, mutect2, varscan2
- WDR77 | c.15C>T p.T5= | Silent (SNP) | VAF 76/173 reads (44%) | catalogued as rs1335542722; called by muse, mutect2, varscan2
- WSCD2 | c.513C>T p.G171= | Silent (SNP) | VAF 230/608 reads (38%) | catalogued as rs766850790, COSV54579301; called by muse, mutect2, varscan2
- ZXDB | c.465G>A p.P155= | Silent (SNP) | VAF 66/236 reads (28%) | catalogued as COSV100885946; called by muse, mutect2, varscan2
- AGAP7P | n.1321C>A | RNA (SNP) | VAF 326/965 reads (34%) | called by muse, mutect2, varscan2
- ARHGEF9 | c.-6A>T | 5'UTR (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- BOD1L1 | c.9039-2594T>G | Intron (SNP) | VAF 41/129 reads (32%) | called by muse, mutect2, varscan2
- C11orf40 | n.324A>T | RNA (SNP) | VAF 37/77 reads (48%) | called by muse, mutect2, varscan2
- CAMKMT | c.377-154703G>T | Intron (SNP) | VAF 39/106 reads (37%) | called by muse, mutect2, varscan2
- CHRND | c.-42T>C | 5'UTR (SNP) | VAF 52/260 reads (20%) | called by muse, mutect2, varscan2
- FAM25C | c.-21G>A | 5'UTR (SNP) | VAF 83/238 reads (35%) | catalogued as rs1298736034; called by muse, mutect2, varscan2
- LIPT2 | chr11:74497683 A>G | 5'Flank (SNP) | VAF 47/119 reads (39%) | catalogued as rs1049166521; called by muse, mutect2, varscan2
- MIR296 | n.56G>C | RNA (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- PRCD | c.*107A>G | 3'UTR (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- SLC6A20 | c.*589G>A | 3'UTR (SNP) | VAF 37/83 reads (45%) | called by muse, mutect2, varscan2
- TAGLN | chr11:117206819 G>A | 3'Flank (SNP) | VAF 55/208 reads (26%) | called by mutect2, varscan2
